Somatic mutation profile of tumor specimen TCGA-B2-5636-01A (aliquot TCGA-B2-5636-01A-02D-1534-10) from TCGA case TCGA-B2-5636, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 79.1 years (28,901 days).
Specimen TCGA-B2-5636-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86de90d0-5cd1-4255-aba0-1ab6a2dd88b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B2-5636-10A (Blood Derived Normal), aliquot TCGA-B2-5636-10A-01D-1535-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c1ac9f6-a849-4968-b892-28ae586d2d6d

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARMIL3 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV100549293, COSV57726154; called by muse, mutect2, varscan2
- HERC5 | c.3049A>G p.I1017V | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99987434; called by muse, mutect2
- INPP5F | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 120/407 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100739995; called by muse, mutect2, varscan2
- KRT6C | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.145); catalogued as COSV99359860; called by muse, mutect2, varscan2
- MYO1D | c.1102T>C p.Y368H | Missense Mutation (SNP) | VAF 221/655 reads (34%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.78); catalogued as COSV100553558; called by muse, mutect2, varscan2
- OR4K15 | c.908C>T p.T303M (on ENST00000305051; = p.T279M on NM_001005486.1) | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs150969455, COSV59301119; called by muse, varscan2
- PRKAG2 | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.903); catalogued as rs1430071393, COSV99834878; called by muse, mutect2
- RB1CC1 | c.2425C>A p.H809N | Missense Mutation (SNP) | VAF 113/447 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV99206813; called by muse, mutect2, varscan2
- RUFY2 | c.1310+2T>A p.X437_splice | Splice Site (SNP) | VAF 188/628 reads (30%) | catalogued as COSV99769143; called by muse, varscan2
- TAMM41 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 77/271 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99808698; called by muse, mutect2, varscan2
- TSHZ2 | c.2052C>G p.N684K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100295479; called by muse, mutect2, varscan2
- TTN | c.90292G>C p.E30098Q (on ENST00000591111; = p.E22674Q on NM_003319.4) | Missense Mutation (SNP) | VAF 47/162 reads (29%) | PolyPhen benign (0.003); catalogued as COSV100596648, COSV60170730; called by muse, mutect2, varscan2
- ZNF16 | c.1789G>A p.G597R | Missense Mutation (SNP) | VAF 112/340 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99429435; called by muse, mutect2, varscan2
- PRRC2B | c.4125G>C p.E1375D | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ACSM4 | c.624C>T p.F208= | Silent (SNP) | VAF 74/234 reads (32%) | catalogued as rs770046219, COSV68067333; called by muse, varscan2
- MFNG | c.669A>C p.T223= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100812857; called by muse, mutect2, varscan2
- RILPL2 | c.213C>T p.V71= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV99760172; called by muse, mutect2, varscan2
- SNRPA | c.564G>A p.Q188= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99698778; called by muse, mutect2, varscan2
